Somatic mutation profile of tumor specimen TCGA-27-1836-01A (aliquot TCGA-27-1836-01A-01D-1494-08) from TCGA case TCGA-27-1836, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 33.0 years (12,060 days).
Specimen TCGA-27-1836-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e3a827dc-6088-4153-b578-fe3571cfc1b7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-27-1836-10A (Blood Derived Normal), aliquot TCGA-27-1836-10A-01D-1494-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1b90129c-ac92-4f74-986b-6a1dc23c0c83

The open-access MAF lists 45 somatic variants for this specimen: 34 protein-altering or splice-affecting, 9 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 9, Frame Shift Del 2, 3'UTR 1, Nonsense Mutation 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- F8 | c.2149C>T p.R717W | Missense Mutation (SNP) | VAF 54/178 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs137852435, CM920257, COSV64271004; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADGRG2 | c.1682del p.P561Rfs*6 (on ENST00000379869 / NM_001079858.3; = p.P558Rfs*6 on NM_005756.4) | Frame Shift Del (DEL) | VAF 34/132 reads (26%) | catalogued as COSV61337657; called by mutect2, pindel, varscan2
- CACNB3 | c.425C>T p.S142F | Missense Mutation (SNP) | VAF 34/122 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.365); catalogued as COSV56399169; called by muse, mutect2, varscan2
- CDH9 | c.1249A>T p.I417L | Missense Mutation (SNP) | VAF 40/133 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.141); catalogued as COSV50308431; called by muse, mutect2, varscan2
- COL11A2 | c.2371G>A p.E791K (on ENST00000341947 / NM_080680.3; = p.E684K on NM_080679.2) | Missense Mutation (SNP) | VAF 33/116 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs752154636, COSV59498424; called by muse, mutect2, varscan2
- DIDO1 | c.4988C>T p.P1663L | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); catalogued as rs961570859, COSV56626083; called by muse, mutect2, varscan2
- DNAH9 | c.7376G>A p.R2459H | Missense Mutation (SNP) | VAF 41/175 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs762156853, COSV52356552; called by muse, mutect2, varscan2
- DNAJB8 | c.185G>A p.R62H | Missense Mutation (SNP) | VAF 63/231 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs201659373, COSV59878988; called by muse, mutect2, varscan2
- EFNA5 | c.278C>G p.T93S | Missense Mutation (SNP) | VAF 83/219 reads (38%) | SIFT tolerated (0.41); PolyPhen benign (0.018); catalogued as COSV60948151, COSV60952284; called by muse, mutect2, varscan2
- ENPP7 | c.253G>A p.G85S | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs150916536, COSV100093788; called by muse, mutect2
- FAM102A | c.532G>A p.G178S (on ENST00000373095 / NM_001035254.3; = p.G36S on NM_203305.2) | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.024); catalogued as COSV55948273; called by muse, mutect2, varscan2
- FAM214B | c.125C>T p.A42V | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0); catalogued as rs902702200, COSV59715612; called by muse, mutect2, varscan2
- GPR31 | c.118C>G p.L40V | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.4); PolyPhen benign (0.029); catalogued as COSV64761624; called by muse, mutect2, varscan2
- HIPK1 | c.1909G>A p.G637R | Missense Mutation (SNP) | VAF 41/114 reads (36%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.996); catalogued as COSV61248745; called by muse, mutect2, varscan2
- IL36A | c.208C>T p.L70F | Missense Mutation (SNP) | VAF 121/376 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.211); catalogued as COSV52083353; called by muse, mutect2, varscan2
- KIF2B | c.98C>T p.A33V | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.184); catalogued as COSV52126814; called by muse, mutect2, varscan2
- KIF4B | c.3055G>A p.E1019K | Missense Mutation (SNP) | VAF 82/265 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.08); catalogued as COSV70530004; called by muse, mutect2, varscan2
- KLK6 | c.340C>T p.R114C | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.283); catalogued as rs200194649, COSV59565296; called by muse, varscan2
- KNG1 | c.1271G>A p.G424E | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT tolerated (0.34); PolyPhen benign (0.018); catalogued as COSV53978798; called by muse, mutect2, varscan2
- LAMC3 | c.3205C>T p.L1069F | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.013); catalogued as COSV63092680; called by muse, mutect2, varscan2
- MIEF2 | c.847A>G p.M283V | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1208618165, COSV59902095; called by muse, varscan2
- NLRP11 | c.1619C>T p.T540M | Missense Mutation (SNP) | VAF 83/284 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs374796362, COSV100789747; called by muse, mutect2, varscan2
- NRDC | c.2944G>A p.G982S | Missense Mutation (SNP) | VAF 178/537 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.212); catalogued as COSV61405626; called by muse, mutect2, varscan2
- OR2T34 | c.709G>A p.A237T | Missense Mutation (SNP) | VAF 71/225 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs746667499, COSV60899605, COSV60900803; called by muse, mutect2, varscan2
- PLA2G3 | c.694G>A p.V232M | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.488); catalogued as rs770485758, COSV53210471; called by muse, mutect2, varscan2
- PPEF1 | c.587A>T p.Y196F | Missense Mutation (SNP) | VAF 145/531 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV62996006; called by muse, mutect2, varscan2
- SLIT3 | c.2054G>A p.S685N | Missense Mutation (SNP) | VAF 54/169 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.334); catalogued as COSV60615505; called by muse, mutect2, varscan2
- SPEF2 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 42/136 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.498); catalogued as rs758346764, COSV56797794; called by muse, mutect2, varscan2
- TLR2 | c.1903C>T p.P635S | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.017); catalogued as rs1322058788, COSV52606523; called by muse, mutect2, varscan2
- TP53 | c.632C>T p.T211I | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV52665474, COSV52751752, COSV52987532; called by muse, mutect2, varscan2
- TTLL12 | c.681G>A p.W227* | Nonsense Mutation (SNP) | VAF 21/74 reads (28%) | catalogued as COSV53355729; called by muse, mutect2, varscan2
- UGT2B10 | c.229C>A p.P77T | Missense Mutation (SNP) | VAF 77/206 reads (37%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.543); catalogued as COSV55321546, COSV55321992, COSV55323739; called by muse, mutect2, varscan2
- ZNF208 | c.1112G>A p.C371Y | Missense Mutation (SNP) | VAF 44/141 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68108421; called by muse, mutect2, varscan2
- KIF13A | c.3271_3272del p.L1091Kfs*13 | Frame Shift Del (DEL) | VAF 61/272 reads (22%) | called by mutect2, pindel, varscan2
- ACADL | c.618T>C p.N206= | Silent (SNP) | VAF 74/220 reads (34%) | catalogued as COSV52053951; called by muse, mutect2, varscan2
- ARL14 | c.561G>A p.A187= | Silent (SNP) | VAF 26/86 reads (30%) | catalogued as rs773857380, COSV57899621; called by muse, mutect2, varscan2
- CABP4 | c.498C>T p.T166= | Silent (SNP) | VAF 24/68 reads (35%) | catalogued as rs139927588; called by muse, mutect2, varscan2
- CELSR1 | c.1194C>T p.D398= | Silent (SNP) | VAF 9/21 reads (43%) | catalogued as rs1231084416, COSV53090082; called by muse, mutect2, varscan2
- IGLV1-36 | c.219G>T p.L73= | Silent (SNP) | VAF 69/226 reads (31%) | catalogued as rs539857340; called by muse, mutect2, varscan2
- MUC2 | c.447C>T p.Y149= | Silent (SNP) | VAF 65/181 reads (36%) | catalogued as rs561164943; called by muse, mutect2, varscan2
- NKTR | c.1122A>G p.A374= | Silent (SNP) | VAF 51/128 reads (40%) | catalogued as rs142015233; called by muse, mutect2, varscan2
- ROBO1 | c.1278C>T p.Y426= | Silent (SNP) | VAF 19/67 reads (28%) | catalogued as COSV71395898; called by muse, mutect2, varscan2
- RYR2 | c.4951C>T p.L1651= | Silent (SNP) | VAF 24/77 reads (31%) | catalogued as COSV63692438; called by muse, mutect2, varscan2
- NXF5 | n.595del | RNA (DEL) | VAF 63/246 reads (26%) | called by mutect2, pindel, varscan2
- OSCAR | c.*419C>T | 3'UTR (SNP) | VAF 9/25 reads (36%) | catalogued as rs148850642; called by muse, mutect2, varscan2
